Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GL, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GL-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

R axillary contents.

FROZEN SECTION REPORT

Fresh tissue (half of the largest node) was taken for tumour banking (Registrar/ Pathologist:

MACROSCOPIC DESCRIPTION

(Dr

"R AXILLARY CONTENTS": A piece of fatty tissue 110 x 50 x 30mm with attached skeletal muscle 60 x 50 x 20mm. The specimen weighs 280g in entirety. No orientating markers are present. Multiple lymph nodes were found upto 3 to 35mm in maximum dimension. Tissue has been taken from the largest node for tumour banking. The lymph nodes were embedded sequentially from one end to the other.

- 1A. One node.
- 1B. Five nodes.
- 1C. Three nodes.
- 1D. One bisected node.
- 1E. Representative section of the largest node.
- 1F. Three nodes.
- 1G. Two nodes.
- 1H. One bisected node.
- 1J. One bisected node.
- 1K. Two nodes.
- 1L. One bisected node.
- 1M. Two nodes.

100-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary C77.3
6/10/11 lw

MICROSCOPIC REPORT

"R AXILLARY CONTENTS": The sections show metastatic malignant epithelioid tumour consistent with melanoma in 2 of 17 lymph nodes. One of the metastases is in the largest 35mm node which is almost effaced (source of tumour banking). The second metastases involves 40% of a small node. No definite extranodal spread is seen.

SUMMARY

Right axillary node dissection - Metastatic melanoma in 2 of 17 lymph nodes.

REPORTED BY: Dr

Primary Tumour Site Discrepancy		X

lw 6/10/11

Source: NCI Genomic Data Commons file 59dec299-8f9a-4e93-bf98-03e74920899b (TCGA-EE-A2GL.6196044A-FF65-4757-B6EC-3557985DA2BF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).